Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8ZM, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8ZM-06A (Metastatic).

[page 1 of 3]
Non Gynae Fine Needle Aspirate

Non Gynae Fine Needle Aspirate

ADDRESS FOR REPORT: PLASTICS

Copy to Cancer Registry

CYTOPATHOLOGY REPORT

LAB No:

ICD-O-3

Melanoma NOS 8720/3

Site: Axilla, subcutaneous

tissue 049.3

Sp 5/19/14

CASE HISTORY:

Malignant melanoma of right index finger in Primary excision
done. Metastasis in right antecubital fossa in and axillary
dissection in Now has a thickening in right axilla. ?
scarring ? melanoma.

MACROSCOPIC:

3 air dried slides dated

MICROSCOPY:

Cellular preparations show atypical, spindle to polygonal cells with
nuclei harbouring multiple nucleoli and nuclear pseudo inclusions.
No excess of lymphoid cells seen in the background. The features are
in keeping with metastatic malignant melanoma.

DIAGNOSIS:

FNA, RIGHT AXILLA: METASTATIC MALIGNANT MELANOMA.

REPORTED BY:

Dr Honorary Registrar, Histopathology
Dr Consultant Histopathologist

REPORT DATE:

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT: PLASTICS

Copy To: n/a

Report to Cancer Registry

HISTOPATHOLOGY REPORT

****SUPPLEMENTARY REPORT**

LAB No:

CASE HISTORY:

Metastatic malignant melanoma

MACROSCOPIC:

Adipose tissue 13 x 11 x 4cm with attached muscle up to 5cm. It

[page 2 of 3]
contains a 3cm lymph node with a haemorrhagic centre (A).

MICROSCOPY:

The largest node contains metastatic melanoma, up to 20 mm diameter. Tumour is present within perinodal fibrous tissue which I suspect is the recent FNA track. 14 other lymph nodes are uninvolved

DIAGNOSIS:

LYMPH NODE, RIGHT AXILLA: METASTATIC MALIGNANT MELANOMA

REPORTED BY:

Dr Consultant Histopathologist

REPORT DATE:

SUPPLEMENTARY REPORT:

The case was sent to for BRAF testing. reports

Sequencing analysis of the BRAF gene has revealed NO MUTATIONS within codon 600 of BRAF gene.

MELANOMA: NO EVIDENCE OF MUTATION WITHIN CODON 600 OF BRAF.

REPORTED BY:

Dr Consultant Histopathologist

Surgical Histology

Surgical Histology

ADDRESS FOR REPORT:

Plastic Surgery

HISTOPATHOLOGY REPORT

LAB No:

Tissue Bank No:

CASE HISTORY:

Tissue banking specimen taken. Stitch to reorientate.

MACROSCOPIC:

Right axilla. Skin ellipse 12.5 x up to 3.1 cm with underlying tissue 11 x 17 cm and to a depth of 3.5 cm. An area on the deep aspect has been inked green and sutured presumably where tissue bank samples have been taken. Deep margin inked green and peripheral margin inked blue. Serial sectioning reveals a pale fibrous area at one peripheral aspect of the specimen. There is a circumscribed pale nodule superior to the sutures and just above the deep margin, 1.1 x 0.9 x 0.8 cm. A = area of fibrosis, peripheral and deep margin. B and C = nodule and deep margin.

MICROSCOPY:

There is a single subcutaneous deposit of metastatic melanoma with a

[page 3 of 3]
REPORT DATE:

HIIPA Discrepancy		☒

Source: NCI Genomic Data Commons file 01ae3ba0-9550-48fc-878f-6c3c9ae60871 (TCGA-WE-A8ZM.154EBBD1-E741-40D4-B7AD-F5BDF49DD1C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).